Surgical pathology report (de-identified scan), TCGA case TCGA-US-A779, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Garvan Institute of Medical Research, specimen TCGA-US-A779-01A (Primary Tumor).

[page 1 of 6]
INTERPRETATION AND DIAGNOSIS:

1. BILE DUCT LYMPH NODE (EXCISION): ONE (1) LYMPH NODE AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.
2. BILE DUCT MARGIN (EXCISION): NEGATIVE FOR TUMOR.
3. PANCREATIC NECK MARGIN (EXCISION): NEGATIVE FOR TUMOR.
4. GALLBLADDER, WHIPPLE AND DISTAL STOMACH (RESECTION):

SPECIMEN TYPE:
Pancreaticoduodenectomy with partial gastrectomy and
cholecystectomy

SITE OF ORIGIN:

Pancreas

TUMOR SITE:
Pancreatic head

HISTOLOGIC TYPE:
Ductal adenocarcinoma

TUMOR SIZE:
Greatest dimension; 3.0 cm

HISTOLOGIC GRADE:
G1: Well differentiated

LYMPH NODES (INCLUDES ALL PARTS):

(Continued on next page.)

ICD-O.3
Adenocarcinoma, ductal NOS
8500/3
Site Pancreas head
C25.0
JW 8/20/13

[page 2 of 6]
Metastatic carcinoma in 2 of 20 nodes

LOCAL EXTENSION:
Wall of duodenum

EXTENT OF INVASION (7th Edition AJCC)
PRIMARY TUMOR:
pT3: Extends beyond the pancreas but without involving the celiac
axis or SMA

REGIONAL LYMPH NODES (pN):
N1b: Metastases in multiple regional nodes

MARGINS:
Margins uninvolved

VENOUS (LARGE) VESSEL INVASION:
Absent

PERINEURAL INVASION:
Absent

ADDITIONAL PATHOLOGIC FINDINGS:
None identified

5. LEFT OVARY (RESECTION): BENIGN OVARIAN CYST (5.0 CM).
LEFT FALLOPIAN TUBE AND OVARY: HISTOLOGICALLY UNREMARKABLE.

* Electronic signature

(Continued on next page.)

[page 3 of 6]
Clinical History:
WHIPPLE

GROSS DESCRIPTION

PART #1: FS: BILE DUCT LYMPH NODE
Resident Pathologist:

FROZEN SECTION DIAGNOSIS:

Staff Pathologist:
Other Pathologists / PAs:
FS: Bile duct lymph node: One (1) lymph node, negative for tumor.

Dictated by:

The specimen is received fresh for frozen section, labeled with the patient's name, and designated 'bile duct lymph node.' The specimen consists of one piece of red-tan soft tissue measuring 1.7 x 1.0 x 0.7 cm in size and there is a possible lymph node measuring 1.4 cm in greatest dimension. The lymph node was bisected and submitted for frozen section. The specimen is submitted in its entirety.

SUMMARY OF SECTIONS

1 - FSC - 2	(LN)
1 - A - 3	(SOFT TISSUE)
2 - TOTAL - 5	

(Continued on next page.)

[page 4 of 6]
PART #2: FS: BILE DUCT MARGIN
Resident Pathologist:

FROZEN SECTION DIAGNOSIS:

Staff Pathologist:
Other Pathologists / PAs:
FS: Bile duct margin: Negative for tumor.

Dictated by:

The specimen is received fresh for frozen section, labeled with the patient's name, and designated 'bile duct margin.' The specimen consists of a cross section of the bile duct with cautery effect measuring 1.5 x 0.7 x 0.3 cm in size. The specimen is submitted in its entirety for frozen section.

SUMMARY OF SECTIONS

1 - FSC - 1
1 - TOTAL - 1

(Continued on next page.)

[page 5 of 6]
PART #3: FS: PANCREATIC NECK MARGIN
Resident Pathologist:

FROZEN SECTION DIAGNOSIS:
Staff Pathologist:
Other Pathologists / PAs:
FS: Pancreatic neck margin: Negative for tumor.

Dictated by:

The specimen is received fresh for frozen section, labeled with the patient's name, and designated 'pancreatic neck margin.'
The specimen consists of one piece of pancreatic tissue with cautery.
The specimen measures 3.0 x 1.7 x 0.3 cm in size. The specimen is submitted in its entirety for frozen section.

SUMMARY OF SECTIONS

1 - FSC - 1
1 - TOTAL - 1

(Continued on next page.)

[page 6 of 6]
SUMMARY OF SECTIONS

1 - FSC T - 1 (FROZEN SECTION TUMOR)
1 - FSC PN - 1 (FROZEN SECTION PANCREATIC NECK)
1 - FSC UM - 1 (FROZEN SECTION UNCINATE MARGIN)
1 - FSC CBD - 1 (FROZEN SECTION COMMON BILE DUCT)
1 - PM - 1 (PROXIMAL MARGIN)
1 - P1 - 1 (NORMAL PANCREATIC TISSUE)
1 - P2 - 1 (NORMAL PANCREATIC TISSUE)
1 - DM - 1 (DISTAL MARGIN)
4 - T1-T4 - 1 EACH (TUMOR)
1 - AMP - 1 (AMPULLA)
2 - CBD1,CBD2 - 1 EA (TUMOR APPROACHING CBD)
1 - DUOD - 1
9 - PST1-PST9 - MULT EA (PERIPANCREATIC SOFT TISSUE)
1 - GB - 4 (GALLBLADDER)
1 - PM1 - 1 (PROXIMAL MARGIN)
1 - DM1 - 1 (DISTAL MARGIN)
MULTIPLE - TOTAL - MULTIPLE

(Continued on next page.)

Source: NCI Genomic Data Commons file 80814e21-885d-4860-853d-9a6010a557a8 (TCGA-US-A779.A6CC54BE-4719-4AB6-853A-824E2FAEC78F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).